Gene-level copy-number profile of tumor specimen TCGA-86-7954-01A from TCGA case TCGA-86-7954, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.6 years (25,062 days).
Specimen TCGA-86-7954-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.2727a745-f95f-4377-a264-5dac84a3dbb6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-7954-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7a54f3ee-d0d8-4314-b775-617a1a17e8de

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,078; copy number 2: 4,841; copy number 3: 12,445; copy number 4: 11,021; copy number 5: 16,030; copy number 6: 7,386; copy number 7: 4,637; copy number 8: 1,175; copy number 9: 649; copy number 10: 79; copy number 11: 5; copy number 12: 112; copy number 13: 5; copy number 14: 6; copy number 15: 16; copy number 16: 19; copy number 17: 47; copy number 18: 28; copy number 19: 13; copy number 20: 39; copy number 22: 51; copy number 24: 56; copy number 25: 14; copy number 27: 1; copy number 28: 19; copy number 32: 24; copy number 33: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-7954-01A-11D-2183-01): tumor purity 0.27, ploidy 4.41, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,581,357–213,021,545, 7 genes (within-gene range 0–3): AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 367 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:19,089,151–20,012,261, 15 genes, copy number 13–33 (within-gene range 5–33): RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3.
- chr12:21,536,203–22,065,674, 10 genes, copy number 11–28 (within-gene range 9–28): AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS.
- chr12:23,637,973–23,638,487, 1 gene, copy number 27: AC087260.1.
- chr12:25,092,715–25,409,445, 11 genes, copy number 17: CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1.
- chr12:25,423,600–25,441,052, 3 genes, copy number 17: AC092451.2, FAM133GP, TUBB4BP1.
- chr12:28,133,249–29,497,686, 20 genes, copy number 17: CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1, AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1.
- chr12:29,519,731–29,529,974, 1 gene, copy number 17: AC009320.1.
- chr12:30,086,342–30,802,602, 13 genes, copy number 19: AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1, IPO8, AC012673.1, CAPRIN2, AC010198.1, LINC00941.
- chr12:31,382,226–31,591,136, 1 gene, copy number 20 (within-gene range 10–20): DENND5B.
- chr12:31,465,062–33,576,200, 57 genes, copy number 12–20: AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P, DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P.
- chr12:34,208,415–34,249,958, 2 genes, copy number 12: DUX4L27, AK6P1.
- chr12:40,393,395–41,072,415, 6 genes, copy number 14 (within-gene range 10–14): MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1.
- chr12:42,454,720–43,552,203, 16 genes, copy number 15: Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20.
- chr12:45,919,131–46,004,685, 2 genes, copy number 18: SCAF11, AC084878.1.
- chr12:49,636,499–50,480,004, 34 genes, copy number 12–22: FMNL3, TMBIM6, AC020612.2, LSM6P2, NCKAP5L, BCDIN3D-AS1, BCDIN3D, AC131157.1, RPL35AP28, FAIM2, LINC02395, LINC02396, AQP2, AC025154.2, AC025154.1, AQP5, AQP6, RACGAP1, ASIC1, SMARCD1, GPD1, COX14, AC074032.1, CERS5, LIMA1, AC008147.2, AC008147.3, AC008147.1, MIR1293, RNU6-1093P, AC008147.4, FAM186A, AC090058.1, LARP4.
- chr12:55,434,734–55,585,471, 1 gene, copy number 12 (within-gene range 5–12): AC122685.1.
- chr12:55,522,593–56,488,414, 80 genes, copy number 12 (broad region; genes not listed).
- chr12:57,415,296–58,244,865, 54 genes, copy number 24: RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103.
- chr12:59,812,102–62,279,150, 12 genes, copy number 12–16 (within-gene range 5–25): AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2, AC090017.1, DUX4L52, AC090629.1, TAFA2, RPL21P104.
- chr12:62,139,999–63,668,939, 28 genes, copy number 16–25 (within-gene range 5–25): AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1, DPY19L2.

Autosomal genes at a single copy (total copy number 1): 1,078. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
